Somatic mutation profile of tumor specimen TCGA-EM-A3FN-01A (aliquot TCGA-EM-A3FN-01A-11D-A21A-08) from TCGA case TCGA-EM-A3FN, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 42.9 years (15,655 days).
Specimen TCGA-EM-A3FN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f40c1a8-844c-4686-bddb-2922cdd47f95.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A3FN-10A (Blood Derived Normal), aliquot TCGA-EM-A3FN-10A-01D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f31b72c-d56f-40e3-b11b-23a6d8ac477e

The open-access MAF lists 14 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Nonsense Mutation 1, Silent 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EIF1AX | c.22G>A p.G8R | Missense Mutation (SNP) | VAF 36/116 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV63309305, COSV63309328; called by muse, mutect2, varscan2
- ACTB | c.598T>G p.F200V | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as COSV59321725; called by muse, mutect2, varscan2
- ADCK1 | c.589G>C p.V197L | Missense Mutation (SNP) | VAF 61/209 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.127); catalogued as COSV53086921; called by muse, mutect2, varscan2
- ARX | c.892C>A p.H298N | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV66875894; called by muse, mutect2, varscan2
- AVP | c.83G>A p.G28D | Missense Mutation (SNP) | VAF 9/257 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66672187, COSV66672270; called by muse, mutect2
- CPOX | c.1087C>A p.P363T | Missense Mutation (SNP) | VAF 17/272 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51640067; called by muse, mutect2
- MOV10L1 | c.2378A>G p.D793G | Missense Mutation (SNP) | VAF 97/297 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.268); catalogued as COSV53180795; called by muse, mutect2, varscan2
- OR5K1 | c.753C>A p.F251L | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as COSV60305515; called by muse, mutect2, varscan2
- PRPF8 | c.2437A>G p.T813A | Missense Mutation (SNP) | VAF 10/161 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV59268476; called by muse, mutect2
- SLC25A13 | c.502G>A p.V168M | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as rs749978956, COSV55714500; called by muse, mutect2, varscan2
- SP1 | c.2129A>G p.N710S (on ENST00000327443 / NM_138473.3; = p.N703S on NM_003109.1) | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.31); catalogued as COSV59405436; called by muse, mutect2
- SYTL3 | c.1601C>G p.S534* (on ENST00000611299 / NM_001242394.1; = p.S466* on NM_001009991.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 41/117 reads (35%) | catalogued as COSV51915873; called by muse, mutect2, varscan2
- TP53BP1 | c.4338C>A p.S1446= | Silent (SNP) | VAF 47/115 reads (41%) | catalogued as COSV55511098; called by muse, mutect2, varscan2
- ANKRD54 | chr22:37844347 del GGGC | 5'Flank (DEL) | VAF 8/17 reads (47%) | called by mutect2, varscan2
